Somatic mutation profile of tumor specimen TCGA-DK-A3IU-01A (aliquot TCGA-DK-A3IU-01A-11D-A20D-08) from TCGA case TCGA-DK-A3IU, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 58.5 years (21,369 days).
Specimen TCGA-DK-A3IU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea93da65-64e9-4afa-999a-6f8218553112.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-A3IU-10A (Blood Derived Normal), aliquot TCGA-DK-A3IU-10A-01D-A20D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76315a89-fa58-43d6-be21-183c3ff24b3e

The open-access MAF lists 416 somatic variants for this specimen: 287 protein-altering or splice-affecting, 121 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 249, Silent 121, Nonsense Mutation 27, Intron 6, Splice Site 4, Frame Shift Del 3, Splice Region 3, 3'UTR 1, 3'Flank 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 19/54 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs112431538, CM123560, CM995136, COSV52661732, COSV52670664, COSV53234441, COSV53650254; ClinVar: drug response / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.803G>A p.R268K | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.839); catalogued as rs1457517086, COSV51703986; called by muse, mutect2, varscan2
- ABCB7 | c.1157G>T p.S386I (on ENST00000373394 / NM_001271696.3; = p.S387I on NM_004299.6) | Missense Mutation (SNP) | VAF 4/83 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV53720221; called by muse, mutect2
- AC023055.1 | c.973+3G>C | Splice Region (SNP) | VAF 18/192 reads (9%) | catalogued as COSV54477828, COSV54479039; called by muse, mutect2
- ACE | c.2806G>T p.V936L | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV52003930, COSV52013949; called by muse, mutect2, varscan2
- ADAMTS16 | c.2278C>T p.Q760* | Nonsense Mutation (SNP) | VAF 17/148 reads (11%) | catalogued as rs749038125, COSV99939747; called by muse, mutect2, varscan2
- ADAMTS2 | c.2541C>A p.N847K | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as COSV52364795, COSV52366033, COSV99283334; called by muse, mutect2, varscan2
- ADCY6 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.681); catalogued as COSV57166470; called by muse, mutect2, varscan2
- AGAP6 | c.530A>G p.H177R (on ENST00000374056 / NM_001365867.1; = p.H200R on NM_001077665.2) | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV100929075; called by muse, mutect2, varscan2
- AHR | c.2466G>C p.Q822H | Missense Mutation (SNP) | VAF 50/220 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.45); catalogued as COSV54121914; called by muse, mutect2, varscan2
- AHSG | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as rs772980949, COSV56607138; called by muse, mutect2, varscan2
- AIM2 | c.612G>C p.K204N | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as COSV63698440, COSV63702008; called by muse, mutect2, varscan2
- AKR1D1 | c.382G>A p.G128R | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs767479014, COSV54336356, COSV99653298; called by muse, mutect2, varscan2
- AMER3 | c.935G>C p.S312T | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as COSV58465409; called by muse, mutect2, varscan2
- AMOTL2 | c.1184G>C p.R395T | Missense Mutation (SNP) | VAF 56/582 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.738); catalogued as COSV51437940; called by muse, mutect2
- ANXA4 | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs144937233; called by muse, mutect2, varscan2
- APC | c.7641G>A p.W2547* | Nonsense Mutation (SNP) | VAF 6/76 reads (8%) | catalogued as COSV99967147; called by muse, mutect2
- ARFGEF2 | c.2437G>A p.E813K | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV64210866; called by muse, mutect2
- ARHGEF1 | c.17G>C p.R6P | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs183598386, COSV61526489; called by muse, mutect2, varscan2
- ARHGEF10 | c.247G>A p.E83K (on ENST00000398564; = p.E59K on NM_014629.4) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.011); catalogued as COSV50642237; called by muse, mutect2
- ARHGEF12 | c.524C>G p.S175C | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.682); catalogued as COSV63103006; called by muse, mutect2, varscan2
- ASAH1 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.034); catalogued as rs776283716, COSV50501399; called by muse, varscan2
- ATG16L1 | c.1189G>A p.D397N (on ENST00000392017 / NM_030803.7; = p.D378N on NM_017974.4) | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as rs750531342, COSV61464492; called by muse, mutect2
- ATN1 | c.308C>G p.S103C | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as rs1555143442, COSV63110345; called by muse, mutect2, varscan2
- ATP10B | c.1831A>G p.S611G | Missense Mutation (SNP) | VAF 28/314 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.062); catalogued as COSV59144751; called by muse, mutect2
- ATRNL1 | c.1888G>A p.G630R | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV61796035, COSV61813253; called by muse, mutect2, varscan2
- B3GNT5 | c.570G>C p.M190I | Missense Mutation (SNP) | VAF 13/195 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58475458; called by muse, mutect2
- B3GNT5 | c.1002G>C p.K334N | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.034); catalogued as COSV58475441, COSV58475474; called by muse, mutect2
- BAZ1B | c.1862C>G p.S621C | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV59989077; called by muse, mutect2
- BCAN | c.990G>C p.K330N | Missense Mutation (SNP) | VAF 26/311 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV61255706, COSV61255943; called by muse, mutect2
- BDNF | c.424G>C p.D142H | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV59233478; called by muse, mutect2, varscan2
- BICDL1 | c.1214C>T p.S405L | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.129); catalogued as rs374769468; called by muse, mutect2, varscan2
- BMP15 | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV53140049; called by muse, mutect2, varscan2
- BTBD2 | c.552G>C p.Q184H | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.03); catalogued as rs1259637010, COSV55307685; called by muse, mutect2, varscan2
- CACNA1G | c.6188C>T p.P2063L | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs758365116, COSV61720864; called by muse, mutect2, varscan2
- CASP6 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.155); catalogued as COSV54460322; called by muse, mutect2, varscan2
- CCN3 | c.387C>A p.F129L | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.096); catalogued as rs781253305, COSV52383155; called by muse, mutect2, varscan2
- CDKL2 | c.948A>T p.K316N | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.548); catalogued as COSV56732384; called by muse, mutect2
- CENPJ | c.2826G>T p.R942S | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV67883066; called by muse, mutect2, varscan2
- CEP89 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.931); catalogued as COSV59862366, COSV59862498; called by muse, mutect2
- CFH | c.2384G>C p.G795A | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66406223; called by muse, mutect2
- CHFR | c.1228G>T p.E410* (on ENST00000432561 / NM_001161345.1; = p.E369* on NM_018223.2) | Nonsense Mutation (SNP) | VAF 28/141 reads (20%) | catalogued as COSV99905209; called by muse, mutect2, varscan2
- CILP2 | c.2536C>T p.R846W | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756251818, COSV52272950; called by muse, mutect2, varscan2
- CLEC16A | c.1994G>T p.R665L | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV68498223; called by muse, mutect2, varscan2
- CLEC4F | c.1069A>T p.T357S | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV55478394; called by muse, mutect2
- CNNM4 | c.2188C>T p.Q730* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as COSV65661544, COSV65661919; called by muse, mutect2, varscan2
- CORO2B | c.527T>C p.I176T | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV55950702; called by muse, mutect2, varscan2
- CPB1 | c.705G>C p.K235N | Missense Mutation (SNP) | VAF 9/152 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51571695, COSV99294507; called by muse, mutect2
- CPNE6 | c.1432G>T p.D478Y | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV53742753, COSV99393510; called by muse, mutect2
- CRNKL1 | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV66105539; called by muse, mutect2
- CTNND2 | c.2464-1G>T p.X822_splice | Splice Site (SNP) | VAF 6/80 reads (8%) | catalogued as rs1365326984, COSV100475018; called by muse, mutect2
- CUBN | c.3035C>T p.S1012F | Missense Mutation (SNP) | VAF 25/219 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.974); catalogued as COSV100913575, COSV64709059; called by muse, mutect2, varscan2
- DAP3 | c.358C>G p.P120A | Missense Mutation (SNP) | VAF 30/223 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58019409; called by muse, mutect2, varscan2
- DCAF4L2 | c.970G>T p.E324* | Nonsense Mutation (SNP) | VAF 9/74 reads (12%) | catalogued as COSV60481119; called by muse, mutect2, varscan2
- DGKZ | c.871G>C p.E291Q (on ENST00000454345 / NM_001105540.2; = p.E102Q on NM_003646.4) | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as COSV58985159; called by muse, mutect2, varscan2
- DHX16 | c.1631C>T p.P544L | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as COSV64563177; called by muse, mutect2
- DIAPH3 | c.1843C>A p.P615T (on ENST00000400324 / NM_001042517.2; = p.P352T on NM_030932.3) | Missense Mutation (SNP) | VAF 48/188 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as COSV57365643; called by muse, mutect2, varscan2
- DNER | c.759A>G p.I253M | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV59160996; called by muse, mutect2, varscan2
- DOLK | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as rs373115419; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DRG1 | c.865C>G p.L289V | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV58918088; called by muse, mutect2, varscan2
- DYNC1H1 | c.13797G>C p.E4599D | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as COSV64134800; called by muse, mutect2
- ECM1 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 32/254 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.061); catalogued as COSV60871938; called by muse, mutect2, varscan2
- EIF2AK2 | c.34G>C p.E12Q | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.9); catalogued as COSV51794979; called by muse, mutect2, varscan2
- EPHA5 | c.1666G>A p.E556K | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV56633552; called by muse, mutect2, varscan2
- EPHB1 | c.1171G>T p.V391F | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67655060, COSV67671851; called by muse, mutect2, varscan2
- EPPK1 | c.6409C>G p.L2137V | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.364); catalogued as COSV73260889; called by muse, mutect2, varscan2
- EPPK1 | c.5620C>T p.R1874C | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs372213876; called by muse, mutect2, varscan2
- ESX1 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 11/236 reads (5%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.03); catalogued as COSV65423977; called by muse, mutect2
- EXOC4 | c.415C>G p.Q139E | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as COSV54085750; called by muse, mutect2, varscan2
- FAM135B | c.3469C>A p.L1157M | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52708627; called by muse, mutect2, varscan2
- FAM135B | c.3409G>A p.D1137N | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52708646; called by muse, mutect2, varscan2
- FAM171A1 | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0.025); catalogued as COSV65313812; called by muse, mutect2, varscan2
- FAM24A | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 59/386 reads (15%) | SIFT tolerated (1); PolyPhen possibly damaging (0.564); catalogued as rs369794433; called by muse, mutect2, varscan2
- FAT4 | c.9277C>T p.Q3093* | Nonsense Mutation (SNP) | VAF 8/61 reads (13%) | catalogued as COSV58704671; called by muse, mutect2, varscan2
- FBN2 | c.2219C>T p.P740L | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM148687, COSV52496077; called by muse, mutect2, varscan2
- FBN3 | c.4705G>C p.E1569Q | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as COSV54454639; called by muse, mutect2, varscan2
- FHOD1 | c.2624C>G p.S875C | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV50759008, COSV99264167, COSV99264512; called by muse, mutect2, varscan2
- FLG2 | c.5750A>G p.K1917R | Missense Mutation (SNP) | VAF 22/330 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.019); catalogued as rs150834303, COSV66166968; called by muse, mutect2
- FLNC | c.7225C>T p.R2409C | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.454); catalogued as rs1244377387, COSV57951527; called by muse, mutect2, varscan2
- FRMPD3 | c.771G>A p.M257I | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as COSV52187209; called by muse, mutect2
- FRY | c.7173G>A p.K2391= | Splice Region (SNP) | VAF 16/188 reads (9%) | catalogued as rs1340938311, COSV66566056, COSV99062018; called by muse, mutect2
- FUCA2 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 11/177 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.158); catalogued as COSV50019742; called by muse, mutect2
- FUT8 | c.1577G>C p.G526A (on ENST00000360689 / NM_001371534.1; = p.G363A on NM_004480.4) | Missense Mutation (SNP) | VAF 19/194 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61280703; called by muse, mutect2
- FZD6 | c.674G>C p.R225T | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV62470750, COSV62472034; called by muse, mutect2, varscan2
- G3BP2 | c.958G>C p.D320H | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV62975814; called by muse, mutect2, varscan2
- GALR2 | c.769C>T p.L257F | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57161653; called by muse, mutect2
- GBF1 | c.413A>T p.Q138L | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.864); catalogued as COSV64143153; called by muse, mutect2, varscan2
- GBF1 | c.4346G>C p.R1449P (on ENST00000369983 / NM_001377137.1; = p.R1448P on NM_004193.3) | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV64143160, COSV64143676; called by muse, mutect2, varscan2
- GC | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV56735626; called by muse, mutect2, varscan2
- GKN2 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 16/284 reads (6%) | SIFT tolerated (0.85); PolyPhen benign (0.011); catalogued as COSV61030967, COSV61031928; called by muse, mutect2
- HAL | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.043); catalogued as COSV54116230, COSV54116625; called by muse, mutect2, varscan2
- HECTD1 | c.7147G>A p.E2383K | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.973); catalogued as COSV67945288; called by muse, mutect2, varscan2
- HELZ | c.419C>G p.S140* | Nonsense Mutation (SNP) | VAF 8/112 reads (7%) | catalogued as COSV62379445; called by muse, mutect2
- HIVEP1 | c.2982G>A p.M994I | Missense Mutation (SNP) | VAF 12/356 reads (3%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV65099198; called by muse, mutect2
- HMCN1 | c.3929G>A p.R1310K | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.114); catalogued as COSV54881200; called by muse, mutect2
- HMGCLL1 | c.875C>T p.T292M | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.072); catalogued as rs201456410, COSV51449306; called by muse, mutect2
- HOXB1 | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759845470, COSV53316559; called by muse, mutect2
- HOXC4 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 18/315 reads (6%) | SIFT tolerated (0.59); PolyPhen benign (0.055); catalogued as COSV57698016; called by muse, mutect2
- HPS4 | c.1504G>A p.A502T | Missense Mutation (SNP) | VAF 36/217 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs767852159, COSV61102685; called by muse, mutect2, varscan2
- HSPA4L | c.513G>A p.M171I | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as COSV56544015; called by muse, mutect2, varscan2
- HTR2B | c.23C>G p.S8C | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV51449104; called by muse, mutect2, varscan2
- ICMT | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.471); catalogued as COSV59473052; called by muse, mutect2
- IFRD2 | c.670C>T p.H224Y | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as COSV57112807; called by muse, mutect2, varscan2
- IGHG1 | c.937G>C p.E313Q | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1349503288; called by muse, varscan2
- IL16 | c.359C>A p.A120E | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.265); catalogued as COSV57260974; called by muse, mutect2, varscan2
- IL1RL1 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs769148023, COSV52112738; called by muse, mutect2, varscan2
- IL36B | c.320A>G p.H107R | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs774779491, COSV52084664; called by muse, mutect2, varscan2
- IMMP2L | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV59221195; called by muse, mutect2
- INTS3 | c.50G>T p.G17V | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.979); catalogued as COSV59675492; called by muse, varscan2
- IPO13 | c.2233G>C p.D745H | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV64893030; called by muse, mutect2
- IQSEC3 | c.2923A>G p.K975E (on ENST00000538872 / NM_001170738.2; = p.K672E on NM_015232.1) | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as rs781947242, COSV58281329; called by muse, mutect2, varscan2
- IRF2 | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66928695; called by muse, mutect2, varscan2
- ITSN2 | c.2471C>T p.A824V | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV61944208; called by muse, mutect2, varscan2
- JAKMIP3 | c.2459G>C p.R820T | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53820545; called by muse, mutect2
- JMJD7-PLA2G4B | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.107); catalogued as COSV59822746; called by muse, mutect2, varscan2
- KCND3 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 10/153 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.405); catalogued as COSV56176146, COSV56187496; called by muse, mutect2
- KIAA2026 | c.1819C>T p.P607S | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.357); catalogued as COSV67353552; called by muse, mutect2
- KIF3A | c.761C>T p.S254L | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66413280; called by muse, mutect2
- KLF5 | c.353C>T p.S118L | Missense Mutation (SNP) | VAF 20/318 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.946); catalogued as COSV66613759; called by muse, mutect2
- KLF6 | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as rs762548312, COSV51493879, COSV51495172; called by muse, varscan2
- KMT2B | c.6016G>C p.E2006Q | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.778); catalogued as COSV55857905, COSV55864123; called by muse, mutect2, varscan2
- KMT2D | c.2782C>T p.Q928* | Nonsense Mutation (SNP) | VAF 15/102 reads (15%) | catalogued as COSV56458548; called by muse, mutect2, varscan2
- KNDC1 | c.356T>C p.F119S | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV58832038; called by muse, mutect2, varscan2
- LAMB1 | c.602C>A p.T201N | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV55962166; called by muse, mutect2, varscan2
- LPA | c.4805C>G p.S1602C | Missense Mutation (SNP) | VAF 9/151 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.753); catalogued as COSV60297892, COSV60306769; called by muse, mutect2
- LRRC2 | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 34/392 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as COSV56125146; called by muse, mutect2
- LRRC37B | c.787G>C p.E263Q | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs1404675362, COSV58951099; called by muse, mutect2
- LRRC40 | c.1437C>G p.L479= | Splice Region (SNP) | VAF 6/48 reads (13%) | catalogued as COSV63941675; called by muse, mutect2
- MAGI3 | c.3913G>A p.E1305K | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.087); catalogued as COSV56829283; called by muse, mutect2
- MAPK9 | c.616G>A p.V206I | Missense Mutation (SNP) | VAF 48/642 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as COSV58119199; called by muse, mutect2
- MARCHF7 | c.790C>G p.Q264E | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV52027661, COSV52027786; called by mutect2, varscan2
- MARF1 | c.3276G>C p.K1092N | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV60020461; called by muse, mutect2
- MAST1 | c.4267C>T p.R1423C | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); catalogued as COSV52241998; called by muse, mutect2, varscan2
- MCM6 | c.1673G>A p.R558K | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.034); catalogued as COSV51465088; called by muse, mutect2, varscan2
- METTL5 | c.19A>G p.K7E | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV53625998; called by muse, mutect2, varscan2
- MGAM | c.3041G>A p.G1014E | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV72073834; called by muse, mutect2, varscan2
- MIA | c.61G>A p.G21S | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54570961; called by muse, mutect2
- MTTP | c.1738C>G p.Q580E | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV55504195; called by muse, mutect2, varscan2
- MUC7 | c.863C>T p.S288F | Missense Mutation (SNP) | VAF 36/319 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV59217250; called by muse, mutect2, varscan2
- MYH11 | c.5000C>T p.S1667F | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs1345711998, COSV55544865; called by muse, mutect2
- MYH2 | c.1688C>G p.S563C | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV55432685; called by muse, mutect2
- MYO16 | c.2497A>G p.N833D | Missense Mutation (SNP) | VAF 13/185 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.907); catalogued as COSV51780018; called by muse, mutect2
- MYO18B | c.4375G>A p.V1459M | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.36); catalogued as rs1200710461, COSV59127025; called by muse, mutect2, varscan2
- MYOM3 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58390547; called by muse, mutect2, varscan2
- NAALADL2 | c.721C>T p.H241Y | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781213832, COSV70295608; called by muse, mutect2, varscan2
- NADSYN1 | c.133G>C p.E45Q | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769946957, COSV59810561; called by muse, mutect2
- NALCN | c.386T>G p.I129S | Missense Mutation (SNP) | VAF 5/115 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV51920855; called by muse, mutect2
- NFATC3 | c.1331G>A p.R444Q | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60471437; called by muse, mutect2
- NFX1 | c.1478C>T p.S493L | Missense Mutation (SNP) | VAF 19/174 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as COSV59308558; called by muse, mutect2, varscan2
- NOX4 | c.446A>T p.E149V | Missense Mutation (SNP) | VAF 15/189 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as rs775523477, COSV54448002; called by muse, mutect2
- NOX4 | c.141C>G p.H47Q | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV54448018; called by muse, mutect2, varscan2
- NPR3 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.516); catalogued as COSV54091475; called by muse, mutect2
- NR1D1 | c.1499G>A p.R500H | Missense Mutation (SNP) | VAF 23/252 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs1262230706, COSV52840965; called by muse, mutect2
- NRXN2 | c.1278C>G p.F426L | Missense Mutation (SNP) | VAF 11/170 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.149); catalogued as COSV55448218, COSV99634631; called by muse, mutect2
- NSD2 | c.2474A>C p.H825P | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV56387197; called by muse, mutect2, varscan2
- NT5DC3 | c.1057T>A p.W353R | Missense Mutation (SNP) | VAF 45/281 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV67321290; called by muse, mutect2, varscan2
- NUDCD1 | c.1663C>T p.P555S | Missense Mutation (SNP) | VAF 37/282 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.301); catalogued as COSV53454509; called by muse, mutect2, varscan2
- NWD1 | c.3370G>A p.D1124N | Missense Mutation (SNP) | VAF 26/298 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.806); catalogued as COSV60337335, COSV60353201; called by muse, mutect2
- OR10J3 | c.353T>C p.V118A | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT tolerated (0.86); PolyPhen benign (0.007); catalogued as rs908365361, COSV59953731; called by muse, mutect2
- OR2M4 | c.662T>A p.V221D | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60707429; called by muse, mutect2, varscan2
- OR4C6 | c.14A>G p.N5S | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.031); catalogued as COSV58602739; called by muse, mutect2, varscan2
- OR5AN1 | c.648G>C p.M216I | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV58321681; called by muse, mutect2
- OR6N2 | c.256C>T p.L86F | Missense Mutation (SNP) | VAF 10/175 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV104411274, COSV59410531; called by muse, mutect2
- OR8H2 | c.167T>G p.L56R | Missense Mutation (SNP) | VAF 30/392 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57943415; called by muse, mutect2
- PARD3 | c.1175G>A p.R392K | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60745952; called by muse, mutect2, varscan2
- PARPBP | c.449C>G p.S150C | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1476078138, COSV59671935; called by muse, mutect2, varscan2
- PCDHB2 | c.920A>G p.Q307R | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.003); catalogued as COSV50564772; called by muse, mutect2
- PCDHGA2 | c.1508C>G p.S503C | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV53907669, COSV53920867; called by muse, mutect2
- PEX7 | c.486C>G p.I162M | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.973); catalogued as COSV59247946; called by muse, mutect2
- PGPEP1 | c.189G>C p.E63D | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.233); catalogued as COSV53252071, COSV53252713; called by muse, mutect2
- PKP2 | c.2135G>A p.G712E | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1348373466, COSV50726425; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLCB1 | c.1298G>C p.G433A | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62040492; called by muse, mutect2, varscan2
- PLCL1 | c.302C>T p.S101L | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as rs1249939618, COSV70822087; called by muse, mutect2, varscan2
- PPFIA1 | c.2575C>T p.Q859* | Nonsense Mutation (SNP) | VAF 6/100 reads (6%) | catalogued as COSV99557290; called by muse, mutect2
- PPP2R5E | c.379C>T p.L127F | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61740175, COSV61740781; called by muse, mutect2, varscan2
- PTGFRN | c.1525G>C p.D509H | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67797880; called by muse, mutect2
- PTGIS | c.1414G>C p.E472Q | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as COSV54835470; called by muse, mutect2, varscan2
- PTPN3 | c.1822G>A p.E608K | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV52702520, COSV99356093; called by muse, mutect2, varscan2
- PTPRK | c.2431C>G p.L811V (on ENST00000368215 / NM_001291984.2; = p.L812V on NM_002844.4) | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.034); catalogued as rs1436393002; called by muse, mutect2
- PUF60 | c.1187C>T p.S396L (on ENST00000526683 / NM_001362896.2; = p.S379L on NM_014281.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV57582887; called by muse, mutect2, varscan2
- RAD54L2 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as COSV56576955; called by mutect2, varscan2
- RAPGEF6 | c.1759G>T p.E587* | Nonsense Mutation (SNP) | VAF 5/20 reads (25%) | catalogued as COSV57243164, COSV99726154; called by muse, mutect2, varscan2
- RB1CC1 | c.641G>C p.R214T | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.244); catalogued as COSV50243534; called by muse, mutect2
- RGS10 | c.40G>C p.D14H (on ENST00000369101; = p.D8H on NM_002925.3) | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs765617830, COSV64861627; called by muse, mutect2, varscan2
- RIPOR1 | c.1093-1G>C p.X365_splice (on ENST00000379312 / NM_001193522.2; = p.X361_splice on NM_024519.4) | Splice Site (SNP) | VAF 4/77 reads (5%) | catalogued as COSV50217698; called by muse, mutect2
- RLIM | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV60325751; called by muse, mutect2
- RNF31 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.039); catalogued as COSV53758604; called by muse, mutect2
- RPS6KA3 | c.1078G>C p.E360Q | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.378); catalogued as COSV65387038; called by muse, mutect2, varscan2
- RPS6KC1 | c.1127G>C p.R376T | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV65297559; called by muse, mutect2, varscan2
- RXRG | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as rs759787868, COSV63231545, COSV63232067; called by muse, mutect2, varscan2
- RYR3 | c.6715G>A p.G2239R | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768589973, COSV63109457, COSV63109700; called by muse, mutect2, varscan2
- SALL4 | c.2808G>C p.E936D | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.82); catalogued as COSV53850213; called by muse, mutect2
- SAMD3 | c.510G>T p.M170I | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV60774307; called by muse, varscan2
- SBF1 | c.3442G>C p.E1148Q | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV62366064; called by muse, mutect2, varscan2
- SCNN1A | c.1460C>T p.S487F | Missense Mutation (SNP) | VAF 18/211 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV57434319, COSV57435517; called by muse, mutect2
- SEL1L3 | c.415C>T p.H139Y | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs376303100; called by mutect2, varscan2
- SERPINA3 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as rs867783314, COSV67585389, COSV67585802; called by muse, mutect2
- SIDT2 | c.2411C>A p.S804Y | Missense Mutation (SNP) | VAF 22/323 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54055487; called by muse, mutect2
- SLC38A3 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101309854; called by muse, mutect2
- SLC4A10 | c.2650C>T p.H884Y (on ENST00000446997 / NM_001354461.2; = p.H854Y on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55766526, COSV99765761; called by muse, mutect2
- SLC4A7 | c.2947C>T p.H983Y | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55395281; called by muse, mutect2, varscan2
- SLFN5 | c.1457G>C p.G486A | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.27); catalogued as COSV55479930, COSV55484100; called by muse, mutect2, varscan2
- SLTM | c.2480G>A p.R827K | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV65848264; called by muse, mutect2, varscan2
- SMARCA2 | c.1100C>T p.S367F | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV61805145; called by muse, mutect2, varscan2
- SMG8 | c.1771G>C p.E591Q | Missense Mutation (SNP) | VAF 8/181 reads (4%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.617); catalogued as COSV56284189; called by muse, mutect2
- SORBS1 | c.3071C>T p.S1024L | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV53353902; called by muse, mutect2, varscan2
- SOS2 | c.211G>C p.E71Q | Missense Mutation (SNP) | VAF 22/228 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs1566478915, COSV53564300; called by muse, mutect2
- SOX6 | c.1418G>A p.G473E (on ENST00000528429 / NM_001145819.2; = p.G432E on NM_017508.3) | Missense Mutation (SNP) | VAF 20/270 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV57038545; called by muse, mutect2
- SOX8 | c.1150G>A p.G384S | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV53508855; called by muse, mutect2
- SPEN | c.9898G>T p.G3300W | Missense Mutation (SNP) | VAF 19/202 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101005781, COSV65358466; called by muse, mutect2
- STON2 | c.1058C>T p.S353F (on ENST00000649389 / NM_001366849.2; = p.S296F on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.664); catalogued as COSV50842618; called by muse, mutect2
- STRBP | c.1240C>A p.H414N | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62117183, COSV99049339; called by muse, mutect2, varscan2
- SYNE1 | c.8766G>C p.E2922D (on ENST00000367255 / NM_182961.4; = p.E2929D on NM_033071.3) | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.888); catalogued as COSV54920125; called by muse, mutect2
- TAF4 | c.2417C>T p.S806F | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.691); catalogued as rs1345489006, COSV53335031; called by muse, mutect2
- TBC1D1 | c.1341G>C p.L447F | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54714940; called by muse, mutect2, varscan2
- TEKT3 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.05); catalogued as COSV58626071; called by muse, mutect2, varscan2
- TG | c.4817-1G>A p.X1606_splice | Splice Site (SNP) | VAF 14/146 reads (10%) | catalogued as COSV55066828, COSV55094826; called by muse, mutect2
- TGFBR3 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV53022312; called by muse, mutect2
- TIMELESS | c.1544G>A p.R515Q | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.227); catalogued as COSV57509406; called by muse, mutect2, varscan2
- TIMELESS | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.765); catalogued as COSV57509419; called by muse, mutect2, varscan2
- TMCC3 | c.610A>G p.R204G | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV54152553; called by muse, mutect2
- TMCO3 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as COSV64806905; called by muse, mutect2
- TMEM106C | c.724G>T p.D242Y | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56742232; called by muse, mutect2, varscan2
- TMEM132E | c.2609C>T p.T870I (on ENST00000321639; = p.T960I on NM_001304438.2) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as COSV58695072; called by muse, mutect2, varscan2
- TMTC3 | c.1387G>C p.E463Q | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.135); catalogued as COSV57122554; called by muse, mutect2
- TNNI1 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.025); catalogued as rs199605300; called by muse, mutect2, varscan2
- TPD52L2 | c.154G>C p.E52Q | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53861654; called by muse, mutect2
- TRIO | c.1424C>T p.S475L | Missense Mutation (SNP) | VAF 12/238 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV60078552; called by muse, mutect2
- TRPC7 | c.320G>T p.G107V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61453734; called by muse, mutect2, varscan2
- TSKS | c.1724G>T p.G575V | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV55873270, COSV55879896; called by mutect2, varscan2
- TTI1 | c.730A>G p.S244G | Missense Mutation (SNP) | VAF 15/194 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65060716; called by muse, mutect2
- UBE2I | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as rs1567146035, COSV57646386; called by muse, mutect2, varscan2
- UBE3A | c.2044A>G p.I682V | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.466); catalogued as COSV51661736; called by muse, mutect2
- UBXN2B | c.359A>T p.Y120F | Missense Mutation (SNP) | VAF 22/344 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV68308700; called by muse, mutect2
- USH2A | c.838C>A p.L280I | Missense Mutation (SNP) | VAF 13/167 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as CM073401, COSV56334216; called by muse, mutect2
- VAV3 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.472); catalogued as COSV64065569; called by muse, mutect2, varscan2
- VCPIP1 | c.2579C>T p.S860F | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as rs1355866668, COSV60046153; called by muse, mutect2
- VPS13B | c.6464G>A p.C2155Y | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.77); catalogued as COSV62134715; called by muse, mutect2, varscan2
- VPS9D1 | c.1670G>T p.G557V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV66994001; called by muse, mutect2, varscan2
- VWCE | c.1908C>G p.F636L | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.682); catalogued as COSV57111194; called by muse, mutect2, varscan2
- WDFY3 | c.7842C>G p.I2614M | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55694653; called by muse, mutect2, varscan2
- WDR36 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.057); catalogued as COSV72411048; called by muse, mutect2
- WDR7 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 17/218 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); catalogued as COSV54348989; called by muse, mutect2
- WWTR1 | c.864G>A p.M288I | Missense Mutation (SNP) | VAF 16/262 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV62290588, COSV62291524; called by muse, mutect2
- YIPF3 | c.487C>G p.L163V | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV58303730; called by muse, mutect2, varscan2
- YTHDC1 | c.1546C>T p.Q516* (on ENST00000344157 / NM_001031732.4; = p.Q498* on NM_133370.4) | Nonsense Mutation (SNP) | VAF 12/91 reads (13%) | catalogued as COSV100704766; called by muse, mutect2, varscan2
- ZCWPW1 | c.1868G>C p.R623T | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.049); catalogued as COSV52199410; called by muse, mutect2
- ZFC3H1 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV57348064; called by muse, mutect2
- ZGRF1 | c.2908G>A p.E970K | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV52199176, COSV52200033; called by muse, mutect2, varscan2
- ZNF35 | c.783G>C p.Q261H | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.976); catalogued as COSV56075773; called by muse, mutect2, varscan2
- ZNF404 | c.961C>T p.H321Y | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60986458; called by muse, mutect2
- ZNF513 | c.1565C>T p.S522F | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.039); catalogued as COSV52006658; called by muse, mutect2
- ZNF526 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.146); catalogued as rs576762112, COSV56628988; called by muse, mutect2, varscan2
- ZNF528 | c.73C>A p.L25M | Missense Mutation (SNP) | VAF 44/202 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64618558; called by muse, mutect2, varscan2
- ZNF99 | c.43C>G p.L15V | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.986); catalogued as rs767282306, COSV68054951; called by muse, mutect2, varscan2
- ZNRF4 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.057); catalogued as rs141487677; called by muse, mutect2, varscan2
- ARID1A | c.2840del p.P947Hfs*21 | Frame Shift Del (DEL) | VAF 13/128 reads (10%) | called by mutect2, pindel, varscan2
- B3GNT5 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2
- BTNL9 | c.361C>T p.H121Y | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.02); called by muse, mutect2
- C2CD5 | c.2012C>G p.S671* | Nonsense Mutation (SNP) | VAF 12/141 reads (9%) | called by muse, mutect2
- CBX8 | c.1144C>T p.Q382* | Nonsense Mutation (SNP) | VAF 18/300 reads (6%) | called by muse, mutect2
- CISH | c.437C>T p.S146F (on ENST00000348721 / NM_145071.4; = p.S163F on NM_013324.6) | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- DLGAP1 | c.928C>T p.Q310* | Nonsense Mutation (SNP) | VAF 13/141 reads (9%) | called by muse, mutect2
- DST | c.21559C>T p.Q7187* (on ENST00000361203 / NM_001374722.1; = p.Q4884* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 16/131 reads (12%) | called by muse, mutect2, varscan2
- EFCAB5 | c.529A>T p.K177* | Nonsense Mutation (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- FUS | c.1100C>A p.S367* | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- GIGYF1 | c.1084C>T p.Q362* | Nonsense Mutation (SNP) | VAF 4/37 reads (11%) | called by muse, mutect2
- GNE | c.40C>T p.Q14* | Nonsense Mutation (SNP) | VAF 22/106 reads (21%) | called by muse, mutect2, varscan2
- GPRASP1 | c.4006C>T p.Q1336* | Nonsense Mutation (SNP) | VAF 8/44 reads (18%) | called by mutect2, varscan2
- HOXB1 | c.851C>T p.S284L | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ITGA6 | c.889del p.L297* (on ENST00000442250; = p.L139* on NM_001316306.2) | Frame Shift Del (DEL) | VAF 12/87 reads (14%) | called by mutect2, pindel, varscan2
- JAG1 | c.3655T>C p.*1219Qext*10 | Nonstop Mutation (SNP) | VAF 22/236 reads (9%) | called by muse, mutect2
- LAMA4 | c.653G>C p.G218A | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LMO7 | c.410C>G p.S137* (on ENST00000357063; = p.S152* on NM_005358.5) | Nonsense Mutation (SNP) | VAF 19/59 reads (32%) | called by muse, mutect2, varscan2
- MLLT6 | c.2442+1G>A p.X814_splice | Splice Site (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2, varscan2
- MRPL40 | c.148C>T p.L50F | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.305); called by muse, mutect2
- NCOA4 | c.976G>C p.E326Q | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.812); called by muse, mutect2
- NEDD1 | c.1910C>G p.S637* | Nonsense Mutation (SNP) | VAF 6/85 reads (7%) | called by muse, mutect2
- NPSR1 | c.1123C>T p.L375F | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.206); called by muse, mutect2
- NUDT4 | c.316G>C p.D106H | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2
- RNF17 | c.3050del p.N1017Ifs*2 | Frame Shift Del (DEL) | VAF 16/114 reads (14%) | called by mutect2, pindel, varscan2
- RYR2 | c.8126C>G p.S2709* | Nonsense Mutation (SNP) | VAF 7/32 reads (22%) | called by muse, mutect2, varscan2
- SYNE2 | c.2396C>G p.S799* | Nonsense Mutation (SNP) | VAF 10/139 reads (7%) | called by muse, mutect2
- TAB3 | c.1168C>T p.Q390* | Nonsense Mutation (SNP) | VAF 6/106 reads (6%) | called by muse, mutect2
- TIGD6 | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 32/285 reads (11%) | called by muse, mutect2, varscan2
- UAP1 | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 9/89 reads (10%) | called by muse, mutect2, varscan2
- ZNF84 | c.1661A>G p.E554G | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.382); called by muse, mutect2
- ABCC9 | c.3468C>T p.A1156= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs201572736, COSV53964012; called by muse, mutect2, varscan2
- ADGRV1 | c.17334G>A p.L5778= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV67979498; called by muse, mutect2
- AK7 | c.795C>T p.V265= | Silent (SNP) | VAF 9/100 reads (9%) | catalogued as COSV50869396; called by muse, mutect2
- ALS2CL | c.2769C>T p.L923= | Silent (SNP) | VAF 5/91 reads (5%) | called by muse, mutect2
- ANKS1B | c.2226C>G p.L742= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV101612674, COSV61337163; called by muse, mutect2, varscan2
- APEH | c.1122G>A p.Q374= | Silent (SNP) | VAF 8/129 reads (6%) | catalogued as COSV56532378; called by muse, mutect2
- ARAP3 | c.2647C>T p.L883= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV53349075; called by muse, mutect2, varscan2
- ARHGAP20 | c.2001G>A p.K667= | Silent (SNP) | VAF 6/63 reads (10%) | catalogued as COSV52807338; called by muse, mutect2
- ATP1A3 | c.2556C>G p.L852= (on ENST00000545399 / NM_001256214.2; = p.L839= on NM_152296.5) | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as COSV57485569; called by muse, mutect2
- ATP6V0B | c.282C>T p.I94= | Silent (SNP) | VAF 11/126 reads (9%) | catalogued as COSV52542693; called by muse, mutect2
- BEX4 | c.354C>T p.L118= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as COSV65515882; called by muse, mutect2, varscan2
- CASP10 | c.927C>T p.I309= (on ENST00000272879 / NM_032974.5; = p.I266= on NM_001230.5) | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV53776908; called by muse, mutect2, varscan2
- CDK5R2 | c.843C>G p.L281= | Silent (SNP) | VAF 7/170 reads (4%) | catalogued as COSV56935652; called by muse, mutect2
- CDK8 | c.102C>T p.H34= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV67419380; called by muse, mutect2, varscan2
- CEP350 | c.2512A>C p.R838= | Silent (SNP) | VAF 22/164 reads (13%) | catalogued as COSV62599343; called by muse, mutect2, varscan2
- CEP76 | c.1947C>T p.I649= | Silent (SNP) | VAF 24/174 reads (14%) | catalogued as COSV50865645; called by muse, mutect2, varscan2
- CFAP58 | c.1287G>A p.Q429= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as COSV57211450; called by muse, mutect2, varscan2
- CHAF1A | c.1536C>G p.L512= | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as COSV56670579, COSV56676420; called by muse, mutect2, varscan2
- CHD8 | c.1038G>A p.Q346= (on ENST00000646647 / NM_001170629.2; = p.Q67= on NM_020920.4) | Silent (SNP) | VAF 10/110 reads (9%) | catalogued as COSV67869795; called by muse, mutect2
- CHFR | c.1227G>T p.L409= (on ENST00000432561 / NM_001161345.1; = p.L368= on NM_018223.2) | Silent (SNP) | VAF 29/145 reads (20%) | catalogued as COSV57172408; called by muse, mutect2, varscan2
- CHL1 | c.2655T>C p.F885= (on ENST00000397491 / NM_001253387.1; = p.F901= on NM_006614.4) | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV56587696; called by muse, mutect2, varscan2
- CNOT1 | c.4677G>A p.L1559= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV55313784; called by muse, mutect2, varscan2
- CSMD3 | c.9957T>C p.F3319= (on ENST00000297405 / NM_001363185.1; = p.F3150= on NM_052900.3) | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as COSV52114520; called by muse, mutect2, varscan2
- CYFIP1 | c.522G>A p.L174= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as rs767926977; called by muse, mutect2, varscan2
- DGKZ | c.1551G>A p.L517= (on ENST00000454345 / NM_001105540.2; = p.L329= on NM_003646.4) | Silent (SNP) | VAF 11/131 reads (8%) | catalogued as rs1442823389, COSV58985183; called by muse, mutect2
- DHRS11 | c.681C>T p.L227= | Silent (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2, varscan2
- DNAAF3 | c.981G>A p.A327= (on ENST00000524407 / NM_001256715.2; = p.A374= on NM_178837.4) | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as rs1481263699, COSV61275433, COSV61276486; called by muse, mutect2, varscan2
- DNAH9 | c.1131C>G p.L377= | Silent (SNP) | VAF 9/133 reads (7%) | catalogued as COSV52337071; called by muse, mutect2
- DNAI2 | c.607C>T p.L203= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV56757106; called by muse, mutect2, varscan2
- DOCK6 | c.4392G>A p.L1464= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV53911533; called by muse, mutect2, varscan2
- EEF1A2 | c.1218G>T p.P406= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as COSV53204952, COSV99419206; called by muse, mutect2
- ENO3 | c.876C>T p.I292= | Silent (SNP) | VAF 35/329 reads (11%) | catalogued as rs759470373, COSV52776290, COSV52777815; called by muse, mutect2, varscan2
- ENPP1 | c.2085T>C p.Y695= | Silent (SNP) | VAF 49/281 reads (17%) | catalogued as COSV62930506; called by muse, mutect2, varscan2
- EXOC6 | c.1920G>A p.L640= | Silent (SNP) | VAF 8/79 reads (10%) | catalogued as COSV53320014; called by muse, mutect2
- FCGBP | c.6780C>T p.F2260= | Silent (SNP) | VAF 8/144 reads (6%) | catalogued as rs1446145333; called by muse, mutect2
- FFAR2 | c.33C>T p.L11= | Silent (SNP) | VAF 10/154 reads (6%) | catalogued as COSV55831855; called by muse, mutect2
- FLT4 | c.1858C>T p.L620= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV56100232, COSV56105141; called by muse, mutect2, varscan2
- GABRA2 | c.51C>T p.F17= | Silent (SNP) | VAF 13/173 reads (8%) | catalogued as rs1180984690, COSV62912430, COSV62914481; called by muse, mutect2
- GABRA4 | c.813G>A p.V271= | Silent (SNP) | VAF 9/46 reads (20%) | called by muse, mutect2
- GALR2 | c.768C>T p.I256= | Silent (SNP) | VAF 4/60 reads (7%) | catalogued as COSV57161652; called by muse, mutect2
- GGT1 | c.1281C>A p.P427= | Silent (SNP) | VAF 17/291 reads (6%) | catalogued as COSV50638316; called by muse, mutect2
- GNAO1 | c.1044C>G p.L348= | Silent (SNP) | VAF 9/103 reads (9%) | catalogued as COSV52611263; called by muse, mutect2
- GRAMD2A | c.915G>A p.L305= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as COSV59032730, COSV59033960; called by muse, mutect2, varscan2
- GUCA1C | c.585C>A p.S195= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV53751535; called by muse, mutect2, varscan2
- HECTD1 | c.4191C>T p.I1397= | Silent (SNP) | VAF 16/276 reads (6%) | catalogued as COSV67945289; called by muse, mutect2
- HTR1A | c.534G>T p.P178= | Silent (SNP) | VAF 36/216 reads (17%) | catalogued as COSV60500021, COSV60501567; called by muse, mutect2, varscan2
- HUWE1 | c.9051G>C p.V3017= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV53336377; called by muse, mutect2, varscan2
- INO80 | c.3153G>A p.L1051= | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as COSV62736441; called by muse, mutect2, varscan2
- ITGA2 | c.1254C>T p.I418= | Silent (SNP) | VAF 4/58 reads (7%) | catalogued as COSV99670017; called by muse, mutect2
- ITIH3 | c.1248C>T p.I416= | Silent (SNP) | VAF 28/240 reads (12%) | catalogued as rs577541241, COSV69648067; called by muse, mutect2, varscan2
- JCAD | c.132G>A p.Q44= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV64758228; called by muse, mutect2, varscan2
- KCNQ5 | c.693C>G p.L231= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as COSV59651348; called by muse, mutect2, varscan2
- KIAA0100 | c.4242C>T p.H1414= | Silent (SNP) | VAF 10/114 reads (9%) | catalogued as rs994356764, COSV66490946; called by muse, mutect2
- KLF6 | c.462G>C p.L154= | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as COSV51493889; called by muse, varscan2
- LRP12 | c.1368C>T p.F456= | Silent (SNP) | VAF 19/136 reads (14%) | catalogued as COSV52626093; called by muse, mutect2, varscan2
- LY75 | c.3192C>G p.L1064= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV55102534; called by muse, mutect2, varscan2
- LYST | c.2613C>T p.L871= | Silent (SNP) | VAF 15/136 reads (11%) | catalogued as COSV67703907; called by muse, mutect2, varscan2
- MAN1A2 | c.1374G>A p.G458= | Silent (SNP) | VAF 18/162 reads (11%) | catalogued as rs759640717, COSV62976489; called by muse, mutect2
- MCM7 | c.972G>C p.L324= | Silent (SNP) | VAF 12/164 reads (7%) | catalogued as COSV57994291; called by muse, mutect2
- MFSD5 | c.960C>T p.L320= | Silent (SNP) | VAF 6/102 reads (6%) | catalogued as rs1027199857, COSV61565182; called by muse, mutect2
- MMP14 | c.75C>T p.L25= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV61287654, COSV61288354; called by muse, mutect2
- MMS22L | c.3159G>A p.L1053= | Silent (SNP) | VAF 23/142 reads (16%) | catalogued as COSV51517241, COSV99247690; called by muse, mutect2, varscan2
- MRPL4 | c.720C>T p.F240= | Silent (SNP) | VAF 8/126 reads (6%) | catalogued as COSV53446789; called by muse, mutect2
- MUC16 | c.36856T>C p.L12286= | Silent (SNP) | VAF 24/131 reads (18%) | catalogued as COSV67448995; called by muse, mutect2, varscan2
- MUC17 | c.13203G>A p.L4401= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV60281622, COSV60285280; called by muse, mutect2, varscan2
- MUC7 | c.39G>A p.L13= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as COSV59217240; called by muse, mutect2, varscan2
- NLRP8 | c.852C>G p.L284= | Silent (SNP) | VAF 30/243 reads (12%) | catalogued as COSV52584032, COSV52590417; called by muse, mutect2, varscan2
- NRXN3 | c.2229C>G p.V743= (on ENST00000335750 / NM_001330195.2; = p.V370= on NM_004796.6) | Silent (SNP) | VAF 5/53 reads (9%) | catalogued as COSV59718733; called by muse, mutect2, varscan2
- ODF1 | c.84C>T p.I28= | Silent (SNP) | VAF 26/183 reads (14%) | catalogued as rs142790437; called by muse, mutect2, varscan2
- OPN3 | c.279C>T p.F93= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV59362793; called by muse, mutect2
- OR10R2 | c.448C>T p.L150= | Silent (SNP) | VAF 61/348 reads (18%) | catalogued as rs1436471551, COSV63768529; called by muse, mutect2, varscan2
- OR5K1 | c.582C>T p.I194= | Silent (SNP) | VAF 16/190 reads (8%) | catalogued as COSV60303666; called by muse, mutect2
- OR8G2P | c.855G>T p.L285= | Silent (SNP) | VAF 7/58 reads (12%) | called by muse, mutect2, varscan2
- OR9Q1 | c.307C>T p.L103= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as COSV59037455; called by muse, mutect2, varscan2
- ORC5 | c.51C>T p.I17= | Silent (SNP) | VAF 13/154 reads (8%) | catalogued as rs1436433646, COSV52396872, COSV99857119; called by muse, mutect2
- PAF1 | c.258C>T p.L86= | Silent (SNP) | VAF 8/114 reads (7%) | catalogued as COSV55392846; called by muse, mutect2
- PAOX | c.969C>T p.I323= | Silent (SNP) | VAF 4/72 reads (6%) | called by muse, mutect2
- PCDHB10 | c.1971G>A p.T657= | Silent (SNP) | VAF 7/69 reads (10%) | catalogued as rs1554284425, COSV53375992; called by muse, mutect2, varscan2
- PCLO | c.10743G>A p.L3581= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as COSV61618951, COSV61644523; called by muse, mutect2
- PCMTD2 | c.543C>T p.L181= | Silent (SNP) | VAF 12/158 reads (8%) | catalogued as rs758186509, COSV55059233, COSV55061479; called by muse, mutect2
- PEG3 | c.1542C>T p.F514= | Silent (SNP) | VAF 30/148 reads (20%) | catalogued as COSV55626710; called by muse, mutect2, varscan2
- PEX5L | c.459G>A p.Q153= | Silent (SNP) | VAF 12/100 reads (12%) | catalogued as rs1424086462, COSV55840227; called by muse, mutect2, varscan2
- PHLDB2 | c.939C>T p.P313= | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as rs142557577; called by muse, mutect2, varscan2
- PLCB2 | c.1980C>T p.F660= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as COSV53031144; called by muse, mutect2, varscan2
- PLEKHH2 | c.3189C>G p.L1063= | Silent (SNP) | VAF 13/106 reads (12%) | catalogued as rs563140716, COSV56750324; called by muse, mutect2, varscan2
- PMF1 | c.111C>T p.L37= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as COSV60771128; called by muse, mutect2
- PPP6R3 | c.2241C>T p.S747= (on ENST00000393800 / NM_001352375.2; = p.S667= on NM_018312.5) | Silent (SNP) | VAF 19/186 reads (10%) | catalogued as COSV55722063; called by muse, mutect2, varscan2
- PPP6R3 | c.2542A>C p.R848= (on ENST00000393800 / NM_001352375.2; = p.R768= on NM_018312.5) | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV55722097; called by muse, mutect2, varscan2
- PTPRF | c.3828C>G p.L1276= | Silent (SNP) | VAF 12/190 reads (6%) | catalogued as COSV63443078; called by muse, mutect2
- RAP2B | c.108C>T p.I36= | Silent (SNP) | VAF 11/165 reads (7%) | catalogued as COSV60256767; called by muse, mutect2
- RECQL | c.1491C>T p.I497= | Silent (SNP) | VAF 7/126 reads (6%) | catalogued as COSV53708271, COSV53709580; called by muse, mutect2
- RP1 | c.270C>T p.H90= | Silent (SNP) | VAF 10/170 reads (6%) | catalogued as COSV55111307; called by muse, mutect2
- SERPINA6 | c.192C>T p.F64= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV58583680; called by muse, mutect2, varscan2
- SERPINA7 | c.27C>G p.L9= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as rs962252959, COSV59664977; called by muse, mutect2, varscan2
- SHROOM3 | c.5550C>T p.S1850= | Silent (SNP) | VAF 27/139 reads (19%) | catalogued as COSV56024159; called by muse, mutect2, varscan2
- SI | c.4374C>A p.L1458= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as rs1238173016, COSV52268110, COSV52296980; called by muse, mutect2
- SIGMAR1 | c.462C>T p.H154= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as rs752975380; called by muse, varscan2
- SLC25A47 | c.909C>T p.A303= | Silent (SNP) | VAF 29/165 reads (18%) | catalogued as COSV59924580; called by muse, mutect2, varscan2
- SLC41A2 | c.1518A>G p.L506= | Silent (SNP) | VAF 15/113 reads (13%) | catalogued as COSV51602509; called by muse, mutect2, varscan2
- SLITRK4 | c.723C>A p.I241= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV62022390; called by muse, mutect2, varscan2
- SORBS1 | c.804G>A p.S268= (on ENST00000361941 / NM_001034954.2; = p.S236= on NM_015385.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/81 reads (14%) | catalogued as rs769152831, COSV53353912, COSV99527395; called by muse, mutect2, varscan2
- SPTB | c.6516G>A p.P2172= | Silent (SNP) | VAF 17/210 reads (8%) | catalogued as rs750379513, COSV61551931; called by muse, mutect2
- TAS1R3 | c.450C>T p.A150= | Silent (SNP) | VAF 22/97 reads (23%) | catalogued as rs1186324010, COSV59562413; called by muse, mutect2, varscan2
- TBC1D8 | c.1050G>A p.E350= | Silent (SNP) | VAF 16/152 reads (11%) | catalogued as COSV65210222; called by muse, mutect2
- TG | c.127C>T p.L43= | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as COSV55066821, COSV99599078; called by muse, mutect2, varscan2
- TMTC1 | c.1401A>T p.S467= (on ENST00000539277 / NM_001193451.2; = p.S359= on NM_175861.3) | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as COSV55476389; called by muse, mutect2
- TMTC2 | c.2322G>A p.L774= | Silent (SNP) | VAF 14/183 reads (8%) | catalogued as COSV58261044; called by muse, mutect2
- TSHZ1 | c.1791G>A p.Q597= (on ENST00000580243 / NM_001308210.2; = p.Q552= on NM_005786.6) | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs767273743, COSV59006269; called by mutect2, varscan2
- TSPEAR | c.579G>A p.V193= | Silent (SNP) | VAF 5/68 reads (7%) | catalogued as COSV59953821; called by muse, mutect2
- TSSK2 | c.78C>A p.V26= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV52816239; called by muse, mutect2, varscan2
- TTC9 | c.648G>A p.Q216= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV56447715; called by muse, mutect2, varscan2
- TXNDC5 | c.426C>T p.F142= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as COSV65729984; called by muse, mutect2, varscan2
- UBASH3B | c.276C>T p.L92= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as COSV52491024; called by muse, mutect2, varscan2
- UBR4 | c.9186C>T p.F3062= | Silent (SNP) | VAF 11/128 reads (9%) | catalogued as COSV64383590; called by muse, mutect2
- UROC1 | c.1701C>T p.F567= | Silent (SNP) | VAF 16/214 reads (7%) | catalogued as COSV52030326; called by muse, mutect2
- USP2 | c.1452G>T p.R484= | Silent (SNP) | VAF 36/421 reads (9%) | catalogued as COSV52727479; called by muse, mutect2
- VCAN | c.6750G>A p.E2250= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as COSV54098270; called by muse, mutect2, varscan2
- WDR19 | c.2796G>C p.L932= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as COSV56462437; called by muse, mutect2, varscan2
- WRNIP1 | c.987G>A p.E329= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs1421375460, COSV66355835; called by muse, mutect2, varscan2
- XAGE5 | c.279A>C p.S93= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV63567646; called by muse, mutect2, varscan2
- ZNF568 | c.1749G>A p.E583= | Silent (SNP) | VAF 6/112 reads (5%) | catalogued as COSV61740639; called by muse, mutect2
- ABCB5 | c.1707+400G>A | Intron (SNP) | VAF 21/216 reads (10%) | catalogued as rs1562544766, COSV51703991; called by muse, mutect2, varscan2
- ETV1 | c.45+322G>A | Intron (SNP) | VAF 12/167 reads (7%) | catalogued as COSV54137745, COSV99622138; called by muse, mutect2
- MCF2L | c.3165+368G>A | Intron (SNP) | VAF 10/51 reads (20%) | called by muse, mutect2, varscan2
- RIMS2 | c.1692+157G>T | Intron (SNP) | VAF 11/142 reads (8%) | catalogued as COSV51657164; called by muse, mutect2
- RPS7 | c.*1A>G | 3'UTR (SNP) | VAF 4/34 reads (12%) | catalogued as COSV100513925; called by muse, mutect2
- TAOK2 | chr16:29991178 G>A | 3'Flank (SNP) | VAF 14/138 reads (10%) | catalogued as rs138517482, COSV54228927; called by muse, mutect2, varscan2
- TTN | c.10361-4928C>G | Intron (SNP) | VAF 6/106 reads (6%) | catalogued as COSV59912417; called by muse, mutect2
- ZNF626 | c.226+277C>T | Intron (SNP) | VAF 7/75 reads (9%) | catalogued as COSV52480351; called by muse, mutect2
